Somatic mutation profile of tumor specimen MBCProject_6127_T2_WES (aliquot MBCProject_6127_T2_WES_1) from CMI case MBCProject_6127, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 38.6 years (14,107 days).
Specimen MBCProject_6127_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e29953fe-c10a-496d-ab76-12b0cd97cfc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6127_SALIVA (Saliva), aliquot MBCProject_6127_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e2191a0-a028-4d37-8d97-af688b0fee33

The open-access MAF lists 55 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Splice Site 3, 5'UTR 3, Nonsense Mutation 2, 5'Flank 2, Intron 2, Frame Shift Del 1, Frame Shift Ins 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.402); catalogued as rs765062000; called by muse, mutect2, varscan2
- CENPF | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs764536623; called by muse, mutect2, varscan2
- CSAD | c.794G>A p.R265H (on ENST00000444623 / NM_001244705.2; = p.R292H on NM_015989.5) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs746315360, COSV57241099; called by muse, mutect2, varscan2
- DDX27 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1283744604, COSV100872093; called by muse, mutect2
- DLG5 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748210887, COSV64948254; called by muse, mutect2, varscan2
- DNAH8 | c.10178C>A p.S3393Y | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59472862; called by muse, mutect2, varscan2
- DNAJC7 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs267604882; called by muse, mutect2, varscan2
- LARP1 | c.2333del p.R778Pfs*27 (on ENST00000518297 / NM_033551.3; = p.R701Pfs*27 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 75/594 reads (13%) | catalogued as COSV60429510; called by mutect2, pindel, varscan2
- LIPA | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1403650234; called by mutect2, varscan2
- MYL10 | c.78+2T>C p.X26_splice | Splice Site (SNP) | VAF 8/140 reads (6%) | catalogued as rs1364564511, COSV56208945; called by muse, mutect2
- PRPF38A | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1193606374, COSV57122753; called by muse, mutect2, varscan2
- SMARCA4 | c.2275-1G>A p.X759_splice | Splice Site (SNP) | VAF 10/181 reads (6%) | catalogued as COSV60791718; called by muse, mutect2
- TRIM2 | c.878C>T p.P293L (on ENST00000437508; = p.P320L on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1279083060, COSV58630714, COSV58631708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR24 | c.1378G>A p.D460N (on ENST00000248142; = p.D330N on NM_032259.4) | Missense Mutation (SNP) | VAF 58/399 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs746133131, COSV50199570; called by muse, mutect2, varscan2
- AMIGO2 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ATP10D | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CELSR1 | c.4717G>T p.D1573Y | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXM1 | c.2015C>A p.S672* | Nonsense Mutation (SNP) | VAF 29/225 reads (13%) | called by muse, mutect2, varscan2
- GJA10 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- HMGN1 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- JMJD6 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2
- MUC2 | c.2589G>A p.M863I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.01); called by muse, mutect2
- NF1 | c.8111_8113+5delinsT p.X2704_splice (on ENST00000358273 / NM_001042492.3; = p.X2683_splice on NM_000267.3) | Splice Site (DEL) | VAF 55/269 reads (20%) | called by pindel, varscan2*
- OR10R2 | c.837C>A p.Y279* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- PLA1A | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- PPP4R3C | c.1371T>G p.S457R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB11FIP1 | c.626_627dup p.D210Kfs*78 | Frame Shift Ins (INS) | VAF 40/301 reads (13%) | called by mutect2, pindel, varscan2
- RASSF2 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC9C2 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SRRM2 | c.2036G>A p.G679D | Missense Mutation (SNP) | VAF 82/680 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMA16 | c.406A>C p.N136H | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNR | c.3172C>G p.L1058V | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); called by muse, mutect2
- TRIM15 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- ADCY2 | c.807G>A p.A269= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs777382356, COSV57903216; called by muse, mutect2, varscan2
- FAT3 | c.7857C>G p.V2619= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- FOXN4 | c.477T>G p.P159= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2
- GTF2H3 | c.297A>T p.G99= | Silent (SNP) | VAF 55/172 reads (32%) | called by muse, mutect2, varscan2
- IQCD | c.462C>T p.N154= | Silent (SNP) | VAF 16/282 reads (6%) | catalogued as rs1484211841; called by muse, mutect2
- NLGN4X | c.1947C>T p.H649= | Silent (SNP) | VAF 39/212 reads (18%) | catalogued as COSV99319414; called by muse, mutect2, varscan2
- OR2G3 | c.624C>A p.V208= | Silent (SNP) | VAF 78/230 reads (34%) | called by muse, mutect2, varscan2
- PASK | c.1185G>A p.A395= | Silent (SNP) | VAF 31/274 reads (11%) | catalogued as rs752960244; called by muse, mutect2, varscan2
- PLD1 | c.15C>T p.N5= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs145738077; called by muse, mutect2, varscan2
- PRAMEF20 | c.1017G>A p.P339= | Silent (SNP) | VAF 102/264 reads (39%) | catalogued as rs948202258; called by muse, mutect2, varscan2
- SEC24C | c.1968G>A p.K656= | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- SLC22A6 | c.792C>T p.Y264= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2
- USP22 | c.1140G>A p.K380= | Silent (SNP) | VAF 41/267 reads (15%) | catalogued as rs1328721529; called by muse, mutect2, varscan2
- ATL1 | c.-35G>T | 5'UTR (SNP) | VAF 79/145 reads (54%) | called by muse, mutect2, varscan2
- ATL1 | c.-34A>G | 5'UTR (SNP) | VAF 82/149 reads (55%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.151+25512G>C | Intron (SNP) | VAF 14/151 reads (9%) | catalogued as rs865967278, COSV51925870; called by muse, mutect2
- CCDC93 | chr2:118014081 T>C | 5'Flank (SNP) | VAF 36/201 reads (18%) | called by muse, mutect2, varscan2
- EXT1 | c.-22C>T | 5'UTR (SNP) | VAF 50/820 reads (6%) | catalogued as rs775296591; called by muse, mutect2
- MIR6511A3 | chr16:16372449 G>A | 3'Flank (SNP) | VAF 22/97 reads (23%) | catalogued as rs1371772489; called by mutect2, varscan2
- PFKFB4 | chr3:48561110 G>A | 5'Flank (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- SLC25A48 | c.813+556C>T | Intron (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- WASF4P | n.883G>C | RNA (SNP) | VAF 29/96 reads (30%) | catalogued as rs373492016; called by muse, mutect2, varscan2
